Surgical pathology report (de-identified scan), TCGA case TCGA-VF-A8AD, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Pennsylvania, specimen TCGA-VF-A8AD-01A (Primary Tumor).

[page 1 of 3]
Panel: Surgical Pathology Report

Date:

- Abnormal Flags key: C Critical H High L Low R Review * Abnormal
- Interpretation Codes: (S) Susceptible (R) Resistant (MS) Moderately Susceptible (I) Intermediate
- Status codes: P-Preliminary F-Final C-Corrected I-In progress/Incomplete X-Cancelled
- Dates and times displayed below are collection dates; to see the observation date and time for a result, hold your course over the collection time. Times are on a 24-hour clock.
- An asterisk [*] in the Note column or next to a panel name indicates a note is present. To view it, rest your mouse cursor on the [*].

Panel	Accession #	Collected	Value	Units	Range	Note
Surgical Pathology Report	██████████ F ██████████	██████████				
Collection d/t:						

Obs d/t:
Ordered by:

Surgical Pathology Report

ICD O 23
Carcinoma, embryonal NOS 9070/3
Tumor, germ cell mixed 9085/3
Site: @ Testis NOS 9022.9
7/25/14

Final Diagnosis

1. Left testis, left radical orchiectomy:

A. Malignant mixed germ cell tumor composed of predominant embryonal carcinoma (~95%) and smaller component of yolk sac tumor (~5%), 1.8 cm; lymphovascular invasion present; tumor invasive into rete testis; tumor does not involve tunica albuginea, spermatic cord or epididymis; see synoptic summary.

B. Spermatic cord margin negative.

The case material was reviewed and the report verified by:

(Electronic signature)

Verification Date:

Note

Immunohistochemical stains were performed for SALL4, AFP, and CD30 on block 1E with adequate controls (see disclaimer). The embryonal carcinoma is positive for OCT4, SALL4, CD30. The yolk sac tumor is positive for SALL4, and AFP. The findings support the above diagnosis.

Disclaimer:

The above in-vitro IHC tests may have used reagents labeled for IVD (In Vitro Diagnostic Use), IUO (Investigational Use Only) and/or RUO (Research Use Only) and have not been cleared or approved by the U.S Food and Drug Administration. However, the FDA has determined that such clearance or approval is not necessary for ASR class I tests intended to provide

[page 2 of 3]
pathologists with adjunctive information to assist their morphologic evaluation. The tests using IUO or IUC reagents were developed and their performance characteristics were validated for diagnostic use by the

This laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical tests. These Class I ASR tests are not intended to provide diagnostic, prognostic, predictive or therapeutic information that is not directly confirmed by routine histopathologic internal or external control specimens.

Synoptic Report

1: Testis, Radical Orchiectomy Summary

SERUM TUMOR MARKERS:

Unknown

SPECIMEN LATERALITY:

Left

TUMOR FOCALITY:

Unifocal

TUMOR SIZE:

Greatest dimension of main tumor mass: 1.8 cm

Additional dimensions: 1.7 x 1.4 cm

MACROSCOPIC EXTENT OF TUMOR:

Confined to the testis

HISTOLOGIC TYPE:

Mixed germ cell tumor: embryonal carcinoma 95%, yolk sac tumor -5%

SPERMATIC CORD MARGIN:

Uninvolved by tumor

OTHER MARGIN(S):

Not applicable

MICROSCOPIC TUMOR EXTENSION:

Re: testis

LYMPH-VASCULAR INVASION:

Present

PRIMARY TUMOR (pT):

pT2: Tumor limited to the testis and epididymis with vascular/lymphatic invasion, or tumor extending through the tunica albuginea with involvement of the tunica vaginalis

REGIONAL LYMPH NODES (pN):

pNX: Cannot be assessed

DISTANT METASTASIS (pM):

Not applicable

SERUM TUMOR MARKER(S):

SX: Serum marker studies not available or performed

ADDITIONAL PATHOLOGIC FINDINGS:

None identified

Pathologist(s)

[page 3 of 3]
Gross Description

The case is received in one fresh container, labeled with the patient's name and medical record number.

Specimen 1 is designated "left testis" and consists of a testis measuring 5.7 x 5.7 x 3.1 cm and attached spermatic cord measuring 9.2 cm in length x 2.5 cm in greatest diameter. The testis and spermatic cord are inked black. The specimen is opened to reveal a firm, vaguely multinodular and heterogeneous tan-brown nodule with focal hemorrhage located in the testis measuring 1.8 x 1.7 x 1.4 cm. The testis was opened to expel 5 cc of serous fluid. No other lesions are grossly identified. Representative sections are submitted as follows: spermatic cord margin shaved in 1A, section from midportion of spermatic cord in 1B, section through base of spermatic cord in 1C, mass in relation to hilar structures in 1D, remainder of the mass submitted in toto in 1E and 1F, representative section of testis in 1G.

SUMMARY OF SECTIONS: Seven, multiple, representative

Dictated by:

Clinical Information

year-old male with heterogeneous solid peripheral enhancing mass in left testicle additional 5 mm lesion in lower left testis

Pre-Operative Diagnosis: Not specified

Post-Operative Diagnosis: Not specified

Operation:

Specific questions to be answered: None

Specimen:

1 Testis, Tumor, Left

*** End of report ***

IHPA Discrepancy		✓

Source: NCI Genomic Data Commons file e851dfe8-313b-4fd6-8b7f-f9d792e1cd13 (TCGA-VF-A8AD.557ABB0F-D774-4ADC-A221-AD0390A598B2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).